Gene-level copy-number profile of tumor specimen TCGA-2H-A9GF-01A from TCGA case TCGA-2H-A9GF, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 67.0 years (24,487 days).
Specimen TCGA-2H-A9GF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.3d8e4263-e968-4479-b01b-fe5050a99e67.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2H-A9GF-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6caca147-cd51-43bb-968c-a8712e207629

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 191; copy number 1: 2,766; copy number 2: 18,922; copy number 3: 25,229; copy number 4: 9,389; copy number 5: 1,704; copy number 6: 1,139; copy number 7: 38; copy number 8: 141; copy number 9: 47; copy number 10: 15; copy number 11: 38; copy number 13: 69; copy number 15: 49; copy number 17: 9; copy number 19: 45; copy number 48: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2H-A9GF-01A-11D-A37B-01): tumor purity 0.68, ploidy 2.84, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 134 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,090,898–9,442,380, 2 genes: RPS26P3, RN7SL5P.
- chr9:20,658,309–20,995,955, 1 gene (within-gene range 0–1): FOCAD.
- chr9:20,786,927–27,284,869, 97 genes (broad region; genes not listed).
- chr18:53,480,825–55,664,787, 28 genes (within-gene range 0–1): LINC01917, LINC01919, RPL29P32, AC090666.1, MBD2, SNORA37, AC093462.1, POLI, STARD6, C18orf54, SNRPGP2, CUPIN1P, AC090897.1, AC091135.1, AC091135.2, DYNAP, RAB27B, RPSAP57, AC007673.1, AC098848.1, CCDC68, MAP1LC3P, LINC01929, RNA5SP459, TCF4, TCF4-AS1, MIR4529, TCF4-AS2.
- chr18:80,147,924–80,247,514, 4 genes (within-gene range 0–1): PARD6G-AS1, PARD6G, AC139100.2, AC139100.1.
- chr20:14,884,250–14,935,363, 2 genes (within-gene range 0–4): MACROD2-AS1, AL138808.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 470 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–1,340,147, 57 genes, copy number 8: BNIP3P41, ZNF595, AC253576.1, ZNF718, AC253576.2, AC108475.1, ZNF876P, AC079140.3, AC079140.5, ZNF732, AC079140.6, AC079140.4, ZNF141, AC079140.1, AC079140.2, MIR571, AC092574.2, ZNF519P4, AC092574.1, ABCA11P, ZNF721, PIGG, TMEM271, AC116565.1, PDE6B, PDE6B-AS1, AC107464.2, ATP5ME, MYL5, SLC49A3, PCGF3, AC107464.1, AC139887.4, AC139887.2, AC139887.1, CPLX1, AC139887.3, AC139887.5, GAK, TMEM175, DGKQ, SLC26A1, IDUA, FGFRL1, AC019103.1, RNF212, AC092535.3, AC092535.4, TMED11P, AC092535.1, AC092535.2, SPON2, AC092535.5, CTBP1-AS, CTBP1, CTBP1-DT, MAEA.
- chr7:50,444,128–53,947,804, 38 genes, copy number 7 (within-gene range 2–7): FIGNL1, DDC, DDC-AS1, GRB10, AC005153.1, AC004920.1, AC009296.1, AC004830.2, AC004830.1, COBL, RPL7L1P2, CICP17, AC012441.2, AC012441.1, AC005999.2, ROBO2P1, AC005999.1, RN7SL292P, AC006478.1, AC006478.2, AC079763.1, AC006320.1, AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P, RN7SKP218, AC009468.2, AC009468.1, LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854.
- chr13:31,739,526–35,673,022, 49 genes, copy number 8 (within-gene range 1–8): RXFP2, AL138708.1, FRY, EEF1DP3, AC002525.1, Metazoa_SRP, FRY-AS1, ZAR1L, BRCA2, IFIT1P1, N4BP2L1, AL137247.1, AL137247.2, N4BP2L2, ATP8A2P2, N4BP2L2-IT2, PDS5B, RNY1P4, AL138820.1, LINC00423, TOMM22P3, KL, STARD13, STARD13-IT1, STARD13-AS, AL627232.1, LINC02344, AL138999.2, AL138999.1, AL139383.1, AL161719.1, AL139081.1, AL139081.2, RFC3, RNU5A-4P, AL161891.1, AL160394.2, VDAC1P12, AL160394.1, AL356321.1, LINC02343, LINC00457, AL161716.1, GAMTP2, Metazoa_SRP, AL138690.1, NBEA, SCAND3P1, PHBP13.
- chr13:40,469,955–43,181,193, 58 genes, copy number 10–19 (within-gene range 1–19): AL133318.1, FOXO1, RLIMP1, MIR320D1, MRPS31, Metazoa_SRP, SLC25A15, MIR621, TPTE2P5, CYCSP34, AL590064.1, SUGT1P3, ELF1, RGS17P1, WBP4, MIR3168, RN7SL597P, KBTBD6, AL354696.2, CALM2P3, KBTBD7, MORF4L1P4, MTRF1, AL354696.1, RAC1P3, NAA16, RNU6-57P, TUBBP2, OR7E36P, OR7E155P, OR7E37P, RGCC, AL354833.2, AL354833.1, VWA8, MIR5006, RN7SL515P, RNU6-74P, KARS1P1, VWA8-AS1, RPS28P8, DGKH, AL157932.1, MAPK6P3, CHCHD2P11, FHP1, AKAP11, LINC02341, FABP3P2, TNFSF11, FAM216B, LINC01050, LINC00428, EPSTI1, ZDHHC4P1, DNAJC15, LINC00400, AL138709.1.
- chr13:43,394,525–43,459,484, 2 genes, copy number 10: RPL36P19, ENOX1-AS2.
- chr13:48,975,912–49,209,779, 1 gene, copy number 15 (within-gene range 1–15): FNDC3A.
- chr13:49,044,079–52,848,641, 102 genes, copy number 9–15 (broad region; genes not listed).
- chr13:63,034,668–63,811,608, 9 genes, copy number 17: AL354810.1, LINC00376, AL359208.1, LINC00395, OR7E156P, AL445989.2, AL445989.1, RNU6-81P, PPP1R2P10.
- chr13:67,266,845–68,986,064, 17 genes, copy number 13: RPSAP53, LINC00364, AL512452.1, BCRP9, NPM1P22, OR7E111P, OR7E33P, AL590027.1, ELL2P3, HNRNPA1P18, RPL37P21, RPS3AP52, RPL12P34, RN7SL761P, LINC00550, LINC02342, ZDHHC20P4.
- chr13:91,023,732–91,354,579, 11 genes, copy number 11: BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1.
- chr13:91,485,793–91,996,523, 2 genes, copy number 11: AL356118.1, AL162456.1.
- chr14:44,924,324–46,501,903, 18 genes, copy number 9 (within-gene range 4–9): KLHL28, TOGARAM1, AL121809.2, AL121809.1, PRPF39, SNORD58, SNORD127, FKBP3, FANCM, MIS18BP1, RNU6-552P, DNAJC19P9, AL162632.3, AL162632.1, AL162632.2, AL139354.1, LINC02303, LINC00871.
- chr17:39,461,486–41,190,639, 106 genes, copy number 8–48 (within-gene range 4–48) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,696. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
